Gene-level copy-number profile of tumor specimen ALCH-AEBV-TTP1-A from ALCHEMIST case ALCH-AEBV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,258 days).
Specimen ALCH-AEBV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 779a1941-18f8-4dda-aacd-69a8fbe726ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEBV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b0ccb045-c276-4585-bbd0-c44abad78c49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 11,704; copy number 2: 41,279; copy number 3: 5,176; copy number 4: 152; copy number 5: 21; copy number 6: 26.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:48,379,834–48,380,132, 1 gene (within-gene range 0–2): RN7SL321P.
- chr5:139,717,985–139,775,472, 4 genes (within-gene range 0–2): RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4.
- chr8:32,927,913–33,045,445, 4 genes: AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr12:57,194,504–57,194,576, 1 gene (within-gene range 0–2): MIR1228.
- chr13:99,404,684–99,417,224, 1 gene: CCR12P.
- chr15:41,774,434–41,899,528, 9 genes (within-gene range 0–1): MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310, AC020659.1.
- chr15:41,908,204–41,908,714, 1 gene (within-gene range 0–1): AC039056.2.
- chr15:64,739,891–64,868,002, 4 genes (within-gene range 0–1): RBPMS2, MIR1272, PIF1, PLEKHO2.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr22:39,570,753–39,689,735, 1 gene: CACNA1I.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 47 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,929,479–42,152,763, 6 genes, copy number 6: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3.
- chr14:18,333,726–18,602,129, 9 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12.
- chr16:81,445,170–82,192,790, 20 genes, copy number 6: CMIP, AC092139.1, PPIAP51, AC092139.2, MIR7854, MIR6504, AC092135.2, AC092135.1, AC092135.3, AC099524.1, PLCG2, RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190.
- chr21:10,413,477–13,120,807, 12 genes, copy number 5: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 10,909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
